MMRF case MMRF_2478 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0982a453-8ddd-40af-b03f-d0160226a0b4

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.2 years (19,060 days); Days to last known disease status: 629 days (1.7 years); Days to last follow up: 629 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 174 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 13 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3290 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.64 g/L; Hemoglobin 4.71 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 256 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 2.48 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 14.5 mmol/L.
- Day 90 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 149 mg/dL; Hemoglobin 7.38 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 239 µmol/L; Blood Urea Nitrogen 21.1 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 10.9 mmol/L.
- Day 209 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 164 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 9.9 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 274 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 6.11 mmol/L.
- Day 279 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 149 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 292 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 21.2 mmol/L.
- Day 370 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 139 mg/dL; Hemoglobin 5.58 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 583 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 15.8 mmol/L.
- Day 433 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 121 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 442 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 10.3 mmol/L.
- Day 545 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 79.7 mg/dL; Immunoglobulin G 9.15 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 380 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 16.9 mmol/L.
- Day 629 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 83.4 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 743 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day 13: Weight: 76 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2478_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 13 days.
- Sample MMRF_2478_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 13 days.
